Somatic mutation profile of tumor specimen TARGET-10-PATRAB-09A (aliquot TARGET-10-PATRAB-09A-01D) from TARGET case TARGET-10-PATRAB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,707 days).
Specimen TARGET-10-PATRAB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b95f1e67-ef7b-44c6-8c51-cdbfadefd412.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATRAB-10A (Blood Derived Normal), aliquot TARGET-10-PATRAB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44ba1ef8-b32a-444a-9e4a-77039800efab

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, In Frame Ins 1, Intron 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IKZF1 | c.476A>G p.N159S | Missense Mutation (SNP) | VAF 60/115 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs374333820, COSV58786758; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CEP89 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as rs1260661351, COSV59865192; called by muse, mutect2, varscan2
- CRBN | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.051); catalogued as COSV51641507; called by muse, mutect2, varscan2
- KCNV1 | c.917A>C p.N306T | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52086880; called by muse, mutect2, varscan2
- OR5D14 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs200387718, COSV59455236; called by muse, mutect2, varscan2
- PIK3CD | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV63128987; called by muse, mutect2
- PIK3R1 | c.1715_1716insTCCTCC p.Q572delinsHPP (on ENST00000521381 / NM_181523.3; = p.Q302delinsHPP on NM_181504.4) | In Frame Ins (INS) | VAF 14/134 reads (10%) | catalogued as COSV99142328; called by mutect2, pindel*
- THBS1 | c.1840G>A p.G614S | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs765144315, COSV52950325; called by muse, mutect2, varscan2
- UNC80 | c.907A>G p.T303A | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV55890234, COSV55895785; called by muse, mutect2, varscan2
- GPR179 | c.1422G>A p.L474= (on ENST00000621958; = p.L473= on NM_001004334.4) | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs1016341206; called by muse, mutect2, varscan2
- POLR2B | c.1794G>A p.V598= | Silent (SNP) | VAF 34/76 reads (45%) | called by muse, mutect2, varscan2
- SBF1 | c.1842G>A p.A614= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs892200506; called by muse, mutect2
- ATP6AP1 | c.*38C>A | 3'UTR (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2
- GAS8 | c.90+1419C>T | Intron (SNP) | VAF 6/50 reads (12%) | catalogued as rs200068483; called by mutect2, varscan2
- MISP | c.-54G>T | 5'UTR (SNP) | VAF 25/50 reads (50%) | called by muse, mutect2, varscan2
